Surgical pathology report (de-identified scan), TCGA case TCGA-CV-5966, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-5966-01A (Primary Tumor).

[page 1 of 4]
***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) CONTENTS RIGHT LEVEL I NECK DISSECTION:
METASTATIC SQUAMOUS CELL CARCINOMA IDENTIFIED IN ONE OF FIVE LYMPH NODES (1/5).
No extracapsular extension
- (B) CONTENTS, LEFT SUPRAOMOHYOID, LEVEL I "A", I "B", II "A", II "B" AND III:
One benign lymph node (0/1) and benign salivary gland tissue within level I "A", no tumor present.
Three benign lymph nodes (0/3) within level I "B", no tumor present.
Two benign lymph nodes (0/2) within level II "A", no tumor present.
Three benign lymph nodes (0/3) within level II "B", no tumor present.
Nine benign lymph nodes (0/9) within level III, no tumor present.
THERE IS SOFT TISSUE INVOLVEMENT OF METASTATIC POORLY DIFFERENTIATED CARCINOMA WITHIN
LEVEL III.
- (C) POSTERIOR LEFT GP SULCUS:
No tumor present.
- (D) LEFT BASE OF TONGUE:
No tumor present.
- (E) RIGHT GINGIVAL MARGIN:
INVASIVE POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA.
- (F) RIGHT FLOOR OF MOUTH:
No tumor present.
- (G) ANTERIOR LABIAL MARGIN:
No tumor present.
- (H) ANTERIOR ORAL TONGUE:
No tumor present.
- (I) COMPOSITE RESECTION LEFT HEMIMANDIBULECTOMY:
INVASIVE POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA (3.0 CM IN DEPTH).
PERINEURAL AND LYMPHOVASCULAR INVASION IDENTIFIED.
- (J) RIGHT GINGIVAL MARGIN, INFERIOR:
No tumor present.
- (K) RIGHT GINGIVAL MARGIN:
No tumor present.
- (L) RIGHT MANDIBLE:
Pending decalcification.
- (M) TEETH:
Benign teeth, gross only.

Entire report and diagnosis completed by

GROSS DESCRIPTION

[page 2 of 4]
(A) CONTENTS RIGHT LEVEL I NECK DISSECTION - An irregular fragment of fibrous adipose tissue (6.0 x 3.0 x 1.5 cm). The specimen is serially sectioned. A possible submandibular gland is present (3.5 x 2.0 x 1.5 cm). In addition to that, four lymph nodes are identified ranging from 0.6 x 0.4 x 0.3 to 1.3 x 0.8 x 0.8 cm.

SECTION CODE: A1, three lymph nodes; A2, one lymph node, bisected; A3, representative sections of submandibular gland.

(B) CONTENTS, LEFT SUPRAOMOHYOID, LEVEL I "A", I "B", II "A", II "B" AND III - Received two irregular masses of adipose tissue, aggregating 11.0 x 6.0 x 2.0 cm. The specimen is oriented by the surgeon in the gross room and separated into the separate levels. The adipose tissue is explored for lymph nodes.

A 2.4 x 1.5 cm, grossly positive lymph node is identified in level III. Multiple levels are identified in the other levels, none of which are grossly positive.

SECTION CODE: B1, four lymph nodes from level I "A" in entirety; B2, B3, a 2.2 x 1.7 x 1.0 cm, grossly negative lymph nodes from level I "B", serially sectioned and entirely submitted; B4, three lymph nodes entirely submitted; B5, two lymph nodes submitted entirely; B6, one lymph node submitted entirely; B7, two lymph nodes, entirely (open level II "A"); B8, one lymph node in entirety (level II "A"); B9, two presumable lymph nodes from level I "B"; B10, three level I "B" lymph node; B11-B13, the largest lymph node (2.4 x 1.5 cm), serially sectioned and entirely submitted; B14, three lymph nodes, entirely; B15, four lymph nodes, entirely; B16, two lymph nodes, entirely; B17, five presumable lymph nodes, entirely.

(C) POSTERIOR LEFT GP SULCUS - A 0.7 x 0.4 x 0.3 cm red-tan, unoriented soft tissue fragment. Submitted entirely in C for frozen section diagnosis.

*FS/DX: SQUAMOUS MUCOSA, NO TUMOR PRESENT.

(D) LEFT BASE OF TONGUE - A 1.7 x 0.4 x 0.3 cm red-tan fragment of soft tissue. Submitted entirely in D for frozen section diagnosis.

*FS/DX: SQUAMOUS MUCOSA WITH SALIVARY GLANDS, NO TUMOR PRESENT.

(E) RIGHT GINGIVAL MARGIN - A 1.2 x 0.4 x 0.2 cm red-tan fragment of soft tissue. Entirely submitted in E for frozen section diagnosis.

*FS/DX: INVASIVE POORLY DIFFERENTIATED CARCINOMA

(F) RIGHT FLOOR OF MOUTH- A 1.0 x 0.4 x 0.4 cm red-tan fragment of soft tissue. Entirely submitted in F for frozen section diagnosis.

*FS/DX: SQUAMOUS MUCOSA WITH SALIVARY GLANDS, NO TUMOR PRESENT.

(G) ANTERIOR LABIAL MARGIN - A 1.7 x 0.4 x 0.4 cm tan fragment of soft tissue. Entirely submitted in G for frozen section diagnosis.

*FS/DX: SQUAMOUS MUCOSA, NO TUMOR PRESENT.

(H) ANTERIOR ORAL TONGUE - A 1.8 x 0.4 x 0.4 cm fragment of red-tan soft tissue. Entirely submitted in H for frozen section diagnosis.

*FS/DX: SQUAMOUS MUCOSA, NO TUMOR PRESENT.

(I) COMPOSITE RESECTION LEFT HEMIMANDIBLE - A 7.5 x 6.0 x 5.2 cm left hemimandibulectomy and glossectomy specimen with tongue (6.0 x 3.0 x 2.0 cm). Four anterior alveoli and four posterior alveoli are identified. An ulcerating spreading infiltrating mucosal tumor is identified involving the entire floor of the mouth, extending from anterior to posterior for 6.0 cm, medial to lateral along the floor of the mouth and involving the base of the tongue for 3.0 cm and invading up to a maximum depth of 2.0 cm. The tumor invades the anterior mandible grossly. Cut sections are fleshy and yellow-white.

SECTION CODE: I1, I2, anterior most section of tumor with possible bone invasion; I3 and I4, one transverse section of tongue with mucosal tumor, entirely; I5-I7, representative sections of tongue and floor of mouth mucosa, from medial portion of resection to posterior portion of glossectomy; I8, representative of tumor, and apparently normal gingival mucosa.

(J) RIGHT GINGIVAL MARGIN, INFERIOR - Two pink-tan strips, 2.0 x 0.7 x 0.3 cm and 1.0 x 0.4 x 0.2 cm.

SECTION CODE: J, entirely submitted.

*FS/DX: SQUAMOUS MUCOSA AND BONE, NO TUMOR PRESENT.

[page 3 of 4]
cc:

(K) RIGHT GINGIVAL MARGIN - A 0.9 x 0.3 x 0.2 cm pink-tan tissue fragment. The specimen is entirely submitted for frozen section. [REDACTED]

(L) RIGHT MANDIBLE - A cross section of mandible (1.6 x 0.9 x 0.6 cm) with a smaller fragment 0.9 x 0.5 x 0.3 cm. Central marrow identified. No definitive tumor is seen.

SECTION CODE: L, entire specimen, after decalcification [REDACTED]

(M) TEETH - Seven intact teeth are received. Gross only [REDACTED]

CLINICAL HISTORY

None given

SNOMED CODES

T-C42000, T-51004, T-53131, T-51200, T-51100, T-11810, M-80703, M-80706, M-00110

"Some tests reported here may have been developed and performance characteristics determined by [REDACTED]. These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Released by: [REDACTED]

[page 4 of 4]
ADDENDUM

DIAGNOSIS

- (I) COMPOSITE RESECTION LEFT HEMIMANDIBULECTOMY:
POORLY DIFFERENTIATED SQUAMOUS CARCINOMA INVADING BONE.
Bony margins of resection of mandible free of tumor.
- (L) RIGHT MANDIBLE:
Bone, no tumor.

Entire report and diagnosis completed by

Released by:

Source: NCI Genomic Data Commons file 53c3b48f-bebc-485c-a223-81384ea55dd7 (TCGA-CV-5966.66D3FA55-1D4C-4FA5-BBC3-352A8EB1F9C5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).